Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BH, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BH-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Addendum *

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED]. Biopsy consistent with high grade pleomorphic sarcoma.

Specimens Submitted:

1: Radical resection right flank

DIAGNOSIS:

1. Radical resection right flank; resection:

- High grade malignant fibrous histiocytoma (undifferentiated pleomorphic sarcoma), pleomorphic type, infiltrating skeletal muscle and fibroadipose tissue, morphologically similar to previous material

- There is a focal myxoid component present composed less than 10% of the tumor.

- Tumor size: 9.7 x 8.0 x 4.0 cm

- Tumor shows about 10% necrosis.

- Vascular invasion is not identified

- Surgical margins are free of tumor; but focally < 0.1 cm microscopic clearance on the inferior margin, posterio-lateral margin and deep margin.

Note: Immunostains for S100 and HMB45 have been ordered, since were not done on the initial biopsy immuno-work-up and the results will be reported as an addendum.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Procedures/Addenda:

[REDACTED]

Addendum Diagnosis

** Continued on next page **

ICD-O-3

Sarcoma, undifferentiated
pleomorphic cell 8805/3
(8802/3)

Code to highest 8805/3

Site Trunk NOS C49.0

path
Trunk NOS C49.1

W11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

1. Radical resection right flank; resection:
- Immunohistochemical stains are negative for S100 and HMB45. The original diagnosis remains unchanged.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the
They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	S100	
	HMB45.	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh, labeled "Right flank, long stitch postero-lateral; short stitch superior" and consists of an oriented, 9.7 x 8.0 x 4.0 cm soft tissue mass with partially overlying, 9.0 x 7.0 x 3.2 cm smooth tan-white skin ellipse. The specimen is oriented as follows: long stitch postero-lateral, short stitch superior. The specimen is inked as follows: Superior -- blue, inferior -- green, postero-lateral -- orange, anterior -- yellow, and deep -- black. The specimen is sectioned to reveal a 6.7 x 6.0 x 3.3 cm, multinodular, firm, diffusely building, well tan-white nodule, located <0.1 cm from both the deep margin and the postero-lateral margin, 0.1 cm from both the superior and inferior margins, 0.2 m from the skin surface, and 1.2 cm from anterior margin. The remaining specimen consists of meaty red muscle surrounded by adipose tissue. Representative sections are submitted to TPS and for permanent. Photographs are taken.

Summary of sections:

SM -- superior margin, perpendicular
IM -- inferior margin, perpendicular
AM -- anterior margin, perpendicular

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 3
PM postero- lateral margin, perpendicular
DM -- deep margin, perpendicular
S -- skin, perpendicular
L -- lesion, sequential sections of greatest dimension of lesion, (superior to inferior)

Summary of Sections:

Part 1: Radical resection right flank

Block	Sect.	Site	PCs
1	AM	1	
1	DM	2	
1	IM	2	
5	L	5	
1	PM	2	
1	S	1	
1	SM	2	

** End of Report **

Criteria	W 10/29/13	Yes	No
Primary Tumor Site Discrepancy	(No Tx)		✓
Prior Malignancy History	check with pathologist	✓	✓

Source: NCI Genomic Data Commons file 49a68e0a-589d-4746-9220-f727e7d16b5e (TCGA-DX-A8BH.36CDEB8A-482E-4105-B7CE-86821736C29F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).